Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6454, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6454-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED] Case ID	[REDACTED] Subject ID	Formatted Path Report
[REDACTED]	[REDACTED]	STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Stomach Tumor size: 8 x 5 x 1.7 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - Esophagus, lesser omentum Lymph nodes: 0/5 positive for metastasis (Regional 0/5) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file 049dd88d-59c9-459b-b602-8266e7a69316 (TCGA-BR-6454.E3B99D2C-C5BF-4705-A9ED-15EBE007D53C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).